CCDI case PBCPHN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7c4dbb0c-ef2a-4577-ade4-77ce16548366

Demographics
Sex at birth: male.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 20.6 years (7,511 days).

Biospecimens (3 samples)
- Sample 0DWLYT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWM0D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWM1M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
